Somatic mutation profile of tumor specimen 0DS290 from CCDI case PBCGTA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 1.0 years (352 days).
Specimen 0DS290: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f33107d-9c3a-4817-9084-8956875de970.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS29R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1f09b13-02fa-465b-b4c2-8e954c15a1b9

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 245/493 reads (50%) | catalogued as rs1260509573, COSV57045054; called by muse, mutect2, varscan2
- IL9R | c.1276T>G p.S426A | Missense Mutation (SNP) | VAF 40/756 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2
- PTPRF | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2
